Somatic mutation profile of tumor specimen TCGA-B8-A54J-01A (aliquot TCGA-B8-A54J-01A-11D-A33K-10) from TCGA case TCGA-B8-A54J, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.4 years (22,071 days).
Specimen TCGA-B8-A54J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5cdc66d-6b90-4b45-a53e-7dddc82a9c0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-A54J-10A (Blood Derived Normal), aliquot TCGA-B8-A54J-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c8bd2b8-e963-4170-ae06-a437fbfe5777

The open-access MAF lists 67 somatic variants for this specimen: 49 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 17, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL2 | c.613G>T p.G205W (on ENST00000502732 / NM_007314.4; = p.G190W on NM_005158.5) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100772942; called by muse, mutect2, varscan2
- ACVRL1 | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV101188112; called by muse, mutect2, varscan2
- APC | c.6899C>G p.S2300C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99969952; called by muse, mutect2, varscan2
- BRD8 | c.2201A>C p.Q734P (on ENST00000254900 / NM_139199.2; = p.Q807P on NM_006696.4) | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99137588; called by muse, mutect2, varscan2
- CAMTA2 | c.1745T>C p.V582A | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100772826; called by muse, mutect2, varscan2
- CASP8AP2 | c.2176G>A p.G726S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99387513; called by muse, mutect2, varscan2
- CEP290 | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV100469664; called by muse, mutect2, varscan2
- CLEC9A | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.326); catalogued as rs754379977, COSV100191438; called by muse, mutect2, varscan2
- COL4A5 | c.649A>C p.N217H | Missense Mutation (SNP) | VAF 102/193 reads (53%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV100089569; called by muse, mutect2, varscan2
- DPH2 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV99356627; called by muse, mutect2, varscan2
- DTL | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100877271; called by muse, mutect2, varscan2
- EAF2 | c.745T>A p.L249M | Missense Mutation (SNP) | VAF 57/290 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99877632; called by muse, mutect2, varscan2
- FREM1 | c.4487A>C p.E1496A | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as COSV101085329; called by muse, mutect2, varscan2
- HIF1A | c.959A>T p.Q320L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100049201; called by muse, mutect2, varscan2
- HRC | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs748293010, COSV99418290; called by muse, mutect2, varscan2
- KIAA1549 | c.4628G>A p.G1543E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99651549, COSV99651823; called by muse, mutect2, varscan2
- KIR2DS4 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.314); catalogued as rs747851004; called by muse, mutect2
- KLHL22 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100186220; called by muse, mutect2, varscan2
- MACF1 | c.15877C>T p.Q5293* (on ENST00000372915; = p.Q3226* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 34/131 reads (26%) | catalogued as COSV99246521; called by muse, mutect2, varscan2
- MAP4K2 | c.1325C>A p.P442H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV99581626; called by muse, mutect2, varscan2
- MRC2 | c.1430G>A p.S477N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100316700; called by muse, mutect2, varscan2
- NAT1 | c.219T>A p.H73Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as COSV100306570; called by muse, mutect2, varscan2
- OR5B3 | c.593T>C p.I198T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV100512066; called by muse, mutect2, varscan2
- PIAS1 | c.1552T>C p.Y518H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV99987083; called by muse, mutect2, varscan2
- PLEKHM3 | c.661A>T p.R221* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV101216840; called by muse, mutect2, varscan2
- PLXNA1 | c.1486C>G p.H496D | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV99303992; called by muse, mutect2, varscan2
- RGS14 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101281748; called by muse, mutect2, varscan2
- RMND5B | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99200958; called by muse, mutect2, varscan2
- ROS1 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100877659, COSV63859947; called by muse, mutect2, varscan2
- RPS4Y1 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99167442; called by muse, mutect2, varscan2
- SCN1B | c.486G>T p.M162I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV99385315; called by muse, mutect2, varscan2
- SEMA3A | c.1970T>C p.I657T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99547837; called by mutect2, varscan2
- SIRT7 | c.316A>T p.T106S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100155718; called by muse, mutect2, varscan2
- SLU7 | c.842A>C p.N281T | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV99775810; called by muse, mutect2, varscan2
- SPATA2 | c.1514A>G p.N505S | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs1453331736, COSV99192947; called by muse, mutect2, varscan2
- SPPL3 | c.48T>A p.S16R | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV100793760; called by muse, mutect2, varscan2
- SPPL3 | c.47G>A p.S16N | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100793761; called by muse, mutect2, varscan2
- TMEM94 | c.3380T>A p.L1127Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100050875; called by muse, mutect2, varscan2
- TTC38 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV101123931; called by muse, mutect2, varscan2
- VRK3 | c.54C>A p.F18L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100371835; called by muse, mutect2, varscan2
- VSNL1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV99723333; called by muse, mutect2, varscan2
- WDTC1 | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as COSV60090816; called by muse, mutect2, varscan2
- ZFYVE26 | c.7141G>C p.G2381R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV100720524, COSV100720693; called by muse, mutect2, varscan2
- ZNF778 | c.289T>G p.S97A | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100124597; called by muse, mutect2, varscan2
- ZNF792 | c.1112G>A p.C371Y | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101289754; called by muse, mutect2, varscan2
- HNRNPH1 | c.1335_1337delinsTT p.Q445Hfs*2 | Frame Shift Del (DEL) | VAF 22/150 reads (15%) | called by pindel, varscan2*
- ITGB1BP2 | c.16del p.R6Vfs*43 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- OR52B6 | c.525_526insA p.F176Ifs*8 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- PBRM1 | c.139-9_141del p.X47_splice | Splice Site (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- ADAMTSL3 | c.4236C>A p.T1412= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99720896; called by muse, varscan2
- AXL | c.90G>A p.T30= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs201764420, COSV56571087; called by muse, mutect2, varscan2
- COL4A1 | c.4459T>C p.L1487= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV101011520, COSV65422659; called by muse, mutect2, varscan2
- CSF2RA | c.612A>G p.Q204= | Silent (SNP) | VAF 58/247 reads (23%) | catalogued as COSV100817938; called by muse, mutect2, varscan2
- EIF4H | c.219C>T p.V73= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs781882111, COSV99733660; called by muse, mutect2, varscan2
- FBXO47 | c.867T>C p.I289= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs936870012, COSV100960857; called by muse, mutect2, varscan2
- MACF1 | c.15876G>A p.Q5292= (on ENST00000372915; = p.Q3225= on NM_012090.5) | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as COSV99246518; called by muse, mutect2, varscan2
- MKLN1 | c.2064T>A p.S688= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100759993; called by muse, mutect2, varscan2
- R3HDML | c.337C>T p.L113= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV99407281; called by muse, mutect2, varscan2
- RPS6KB1 | c.570T>C p.F190= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV99847726; called by muse, mutect2, varscan2
- SMG6 | c.2556C>G p.R852= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV99558669; called by muse, mutect2, varscan2
- TBC1D26 | c.345A>G p.L115= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs554614861, COSV101343685; called by muse, mutect2, varscan2
- TCFL5 | c.930C>G p.S310= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99416120; called by muse, mutect2, varscan2
- TSC1 | c.399C>T p.V133= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV100052490; called by muse, mutect2, varscan2
- TUBE1 | c.54C>T p.C18= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV100898197; called by muse, mutect2, varscan2
- TXNDC16 | c.33G>T p.G11= | Silent (SNP) | VAF 36/156 reads (23%) | catalogued as rs745458731, COSV99909602; called by muse, mutect2, varscan2
- VSNL1 | c.450A>G p.R150= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV54600360; called by muse, mutect2, varscan2
- ACAD9 | c.*23T>A | 3'UTR (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100459402; called by muse, mutect2, varscan2
